Somatic mutation profile of tumor specimen 0DWYWG from CCDI case PBCMKC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Spindle cell carcinoma, NOS; Tissue or organ of origin: Vagina, NOS; Age at diagnosis: 15.6 years (5,705 days).
Specimen 0DWYWG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 860bb1cd-056e-4a92-8034-1e9151f6d2d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWYUL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a96ec1ee-5958-4e91-bb97-3fc489393849

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GGNBP2 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 86/687 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.682); catalogued as rs752364975; called by muse, varscan2
- MUC4 | c.2690C>A p.S897Y | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.618); catalogued as rs567447469; called by muse, varscan2
- NEUROD6 | c.460A>G p.K154E | Missense Mutation (SNP) | VAF 104/655 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, varscan2
- PPP6R3 | c.438del p.K146Nfs*5 | Frame Shift Del (DEL) | VAF 62/604 reads (10%) | called by pindel, varscan2
- PTPRS | c.4235A>T p.N1412I | Missense Mutation (SNP) | VAF 62/354 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TONSL | c.531G>T p.Q177H | Missense Mutation (SNP) | VAF 150/658 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, varscan2
- EZH2 | c.465G>T p.G155= | Silent (SNP) | VAF 120/790 reads (15%) | called by muse, varscan2
- RELN | c.6870C>A p.R2290= | Silent (SNP) | VAF 88/816 reads (11%) | called by muse, varscan2
- TONSL | c.39G>T p.A13= | Silent (SNP) | VAF 72/298 reads (24%) | called by muse, varscan2
- PLCXD2 | c.*104G>A | 3'UTR (SNP) | VAF 128/1060 reads (12%) | called by muse, varscan2
